Somatic mutation profile of tumor specimen TCGA-DJ-A2PN-01A (aliquot TCGA-DJ-A2PN-01A-21D-A19J-08) from TCGA case TCGA-DJ-A2PN, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 70.3 years (25,690 days).
Specimen TCGA-DJ-A2PN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 051e7a2e-fb4a-4c44-8945-fc7a06db9f67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A2PN-10A (Blood Derived Normal), aliquot TCGA-DJ-A2PN-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0ce8cd9-3df5-4e64-a704-101fb690ace3

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- LRRC7 | c.3848C>T p.S1283L (on ENST00000651989 / NM_001370785.2; = p.S1250L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as COSV50580814; called by muse, mutect2, varscan2
- MTMR12 | c.1260G>C p.Q420H | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53783081, COSV53787199; called by muse, mutect2
- PIBF1 | c.1427A>T p.E476V | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58327296; called by muse, mutect2, varscan2
- VGLL3 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.207); catalogued as rs368641887; called by mutect2, varscan2
- DNAAF5 | c.873C>T p.L291= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as COSV52416301, COSV52420310; called by muse, mutect2
- PDP1 | c.723G>A p.K241= | Silent (SNP) | VAF 43/102 reads (42%) | catalogued as COSV52603501; called by muse, mutect2, varscan2
